Somatic mutation profile of tumor specimen ALCH-B3AP-TTP1-A (aliquot ALCH-B3AP-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B3AP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 67.0 years (24,487 days).
Specimen ALCH-B3AP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46cf9601-124e-4f90-aafc-a405b9e696e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3AP-NB1-A (Blood Derived Normal), aliquot ALCH-B3AP-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/403ee3d9-21b2-4a22-b871-b1343eb237b2

The open-access MAF lists 308 somatic variants for this specimen: 195 protein-altering or splice-affecting, 73 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 174, Silent 73, Intron 20, Nonsense Mutation 11, RNA 8, 3'UTR 5, Frame Shift Del 5, 5'UTR 4, Splice Region 3, Splice Site 2, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 158/746 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACAA2 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 24/451 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.224); catalogued as rs149964586; called by muse, mutect2
- ACOD1 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575883734, COSV66291478; called by muse, mutect2, varscan2
- ADAMTS20 | c.4510G>A p.G1504S | Missense Mutation (SNP) | VAF 39/368 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.939); catalogued as rs1178451668; called by muse, mutect2, varscan2
- AHRR | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 24/351 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs779590183, COSV57084132; called by muse, mutect2
- AMER2 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs745945541, COSV63437872; called by muse, mutect2, varscan2
- ATAD3B | c.670G>T p.D224Y (on ENST00000308647; = p.D330Y on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/458 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100426600; called by muse, mutect2, varscan2
- CCER1 | c.1206G>T p.Q402H | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV100727114; called by muse, mutect2, varscan2
- CD36 | c.311C>A p.T104N | Missense Mutation (SNP) | VAF 77/657 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.393); catalogued as rs1398779645; called by muse, mutect2, varscan2
- COL6A6 | c.5891T>A p.M1964K | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs758203576; called by muse, mutect2, varscan2
- CRISP2 | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 90/692 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100189124; called by muse, mutect2, varscan2
- CSMD1 | c.8608G>A p.V2870I (on ENST00000520002; = p.V2869I on NM_033225.6) | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs372737280, COSV59328414; called by muse, mutect2, varscan2
- DBX2 | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99081870; called by muse, mutect2, varscan2
- DCC | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 56/612 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1003873682, COSV59096849; called by muse, mutect2
- DMBT1 | c.6145G>T p.A2049S (on ENST00000338354 / NM_001377530.1; = p.A1292S on NM_004406.3) | Missense Mutation (SNP) | VAF 66/398 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1565974008; called by muse, mutect2, varscan2
- DNHD1 | c.7873C>T p.R2625W | Missense Mutation (SNP) | VAF 72/489 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs1350846579; called by muse, mutect2, varscan2
- DOCK10 | c.4339A>C p.K1447Q | Missense Mutation (SNP) | VAF 42/622 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV51382931; called by muse, mutect2
- FLG | c.1844G>A p.R615K | Missense Mutation (SNP) | VAF 331/1383 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.235); catalogued as rs757414270; called by muse, mutect2, varscan2
- FREM1 | c.6473G>T p.G2158V | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as COSV66530542; called by muse, mutect2, varscan2
- HS3ST1 | c.306G>C p.W102C | Missense Mutation (SNP) | VAF 28/472 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560230864, COSV50026602; called by muse, mutect2
- HTR3A | c.1192C>A p.P398T | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV55468678; called by muse, mutect2
- IL1RAPL2 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV61142564; called by muse, mutect2, varscan2
- INPP4B | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 54/643 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.086); catalogued as COSV53723386, COSV53733605; called by muse, mutect2
- IRX3 | c.1229A>G p.N410S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1414658791; called by muse, varscan2
- ITGAM | c.3068G>T p.C1023F (on ENST00000648685 / NM_001145808.2; = p.C1022F on NM_000632.4) | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489744796; called by muse, mutect2
- KALRN | c.1592G>T p.R531L | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53753202; called by muse, mutect2, varscan2
- KCNN4 | c.1012C>A p.R338S | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767025386, COSV53455194; called by muse, mutect2, varscan2
- KDR | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 17/467 reads (4%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.996); catalogued as COSV55769435; called by muse, mutect2
- KRT73 | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 20/230 reads (9%) | catalogued as COSV59841260; called by muse, mutect2
- KRT79 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as COSV57939736; called by muse, mutect2, varscan2
- LEP | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 45/361 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV100451321, COSV58241590; called by muse, mutect2, varscan2
- MARK1 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 39/296 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs767899528; called by muse, mutect2, varscan2
- MCHR2 | c.240G>T p.L80F | Missense Mutation (SNP) | VAF 52/425 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs78660011, COSV99029585; called by muse, mutect2, varscan2
- MEGF8 | c.6503G>T p.G2168V (on ENST00000251268 / NM_001271938.2; = p.G2101V on NM_001410.3) | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV52090607; called by muse, mutect2, varscan2
- MPO | c.1969G>T p.V657L | Missense Mutation (SNP) | VAF 54/382 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs774394797, COSV51858210; called by muse, mutect2, varscan2
- NCOR2 | c.4576G>T p.A1526S | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.291); catalogued as COSV100658266; called by muse, mutect2
- NLRP14 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 110/885 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100204979; called by muse, mutect2, varscan2
- NMRK2 | c.518T>A p.M173K | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as rs138618157, COSV51456831; called by muse, mutect2, varscan2
- NOC2L | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as rs3828050, COSV58990546; called by muse, mutect2, varscan2
- NOTCH4 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.189); catalogued as COSV66678698; called by muse, mutect2
- PCDHGA11 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs771844166; called by muse, mutect2, varscan2
- PDHA2 | c.197T>C p.M66T | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54777227; called by muse, mutect2
- PIAS3 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1204452226; called by muse, mutect2, varscan2
- PIK3R5 | c.34C>A p.R12S | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99353893; called by muse, mutect2, varscan2
- RAG1 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 27/323 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs372110434; ClinVar: uncertain significance; called by muse, mutect2
- RIPOR2 | c.2485A>T p.S829C | Missense Mutation (SNP) | VAF 58/683 reads (8%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.847); catalogued as COSV52417543; called by muse, mutect2
- RYR2 | c.14092C>T p.L4698= | Splice Region (SNP) | VAF 18/99 reads (18%) | catalogued as COSV100767332; called by muse, varscan2
- SEMA5A | c.1051C>A p.P351T | Missense Mutation (SNP) | VAF 30/367 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369356589; called by muse, mutect2
- SLC22A12 | c.1300del p.R434Afs*33 | Frame Shift Del (DEL) | VAF 23/193 reads (12%) | catalogued as CM1110339; called by mutect2, pindel, varscan2
- TMPRSS11F | c.625G>T p.G209* | Nonsense Mutation (SNP) | VAF 40/778 reads (5%) | catalogued as COSV62469860; called by muse, mutect2
- TMTC2 | c.416G>C p.R139P | Missense Mutation (SNP) | VAF 48/346 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762061799; called by muse, mutect2, varscan2
- TRPA1 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 46/721 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1465233747, COSV51564788; called by muse, mutect2
- TSPAN17 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as rs141018454; called by muse, mutect2, varscan2
- UBN1 | c.1916G>A p.R639K | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.931); catalogued as rs1000756785; called by muse, mutect2
- ZDBF2 | c.5561G>C p.R1854P | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV65626819; called by muse, mutect2, varscan2
- ZFHX4 | c.4483C>A p.H1495N | Missense Mutation (SNP) | VAF 49/343 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as COSV50781301; called by muse, mutect2, varscan2
- ZFHX4 | c.4877T>C p.L1626P | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs766253878; called by muse, mutect2, varscan2
- ZNF521 | c.443G>T p.C148F | Missense Mutation (SNP) | VAF 60/348 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64129272; called by muse, mutect2, varscan2
- ZNF98 | c.1370C>T p.T457I | Missense Mutation (SNP) | VAF 36/612 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV63340401; called by muse, mutect2
- AEBP1 | c.428A>T p.K143M | Missense Mutation (SNP) | VAF 132/1060 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- AP5B1 | c.866_876del p.L289Pfs*44 | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | called by mutect2, pindel, varscan2
- ATP2B3 | c.185G>T p.R62M | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- ATRX | c.3943G>T p.E1315* | Nonsense Mutation (SNP) | VAF 115/367 reads (31%) | called by muse, mutect2, varscan2
- ATXN1 | c.1873G>T p.G625C | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AXIN2 | c.719_743del p.K240Mfs*8 | Frame Shift Del (DEL) | VAF 38/248 reads (15%) | called by mutect2, pindel
- BMP1 | c.647del p.G216Afs*35 | Frame Shift Del (DEL) | VAF 44/476 reads (9%) | called by mutect2, pindel
- C9orf50 | c.1202C>A p.P401H | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CA2 | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 70/758 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CAMSAP2 | c.4024G>T p.A1342S (on ENST00000236925 / NM_001297707.2; = p.A1331S on NM_203459.3) | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- CCSER2 | c.2396C>G p.P799R | Missense Mutation (SNP) | VAF 96/699 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- CDH4 | c.877G>C p.G293R | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.455); called by muse, mutect2
- CDH8 | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 47/566 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CDR1 | c.545G>A p.W182* | Nonsense Mutation (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2, varscan2
- CELSR2 | c.1879A>C p.T627P | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CEP290 | c.5433A>T p.R1811S | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- CES2 | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 36/487 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- CNGA2 | c.1786G>T p.D596Y | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- CNN2 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.048); called by muse, varscan2
- CNTNAP2 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 76/769 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- COL14A1 | c.256A>T p.I86F | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL1A2 | c.1612-1G>T p.X538_splice | Splice Site (SNP) | VAF 122/1356 reads (9%) | called by muse, mutect2
- COL3A1 | c.1841C>A p.T614N | Missense Mutation (SNP) | VAF 45/913 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.139); called by muse, mutect2
- CR2 | c.1675G>T p.G559W | Missense Mutation (SNP) | VAF 116/636 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRACR2A | c.1706G>C p.R569P | Missense Mutation (SNP) | VAF 61/478 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- CSMD3 | c.10874G>T p.G3625V (on ENST00000297405 / NM_001363185.1; = p.G3456V on NM_052900.3) | Missense Mutation (SNP) | VAF 32/431 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- CSMD3 | c.1415C>G p.S472C (on ENST00000297405 / NM_001363185.1; = p.S368C on NM_052900.3) | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- DGKZ | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 65/508 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- DICER1 | c.4618G>T p.G1540* | Nonsense Mutation (SNP) | VAF 85/838 reads (10%) | called by muse, mutect2
- DIO2 | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 68/726 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2
- DLGAP5 | c.124A>T p.N42Y | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, varscan2
- DMXL1 | c.3135G>T p.R1045S | Missense Mutation (SNP) | VAF 94/475 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- DNAH3 | c.8579G>T p.R2860L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DRC7 | c.368G>T p.C123F | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- DSC3 | c.593C>A p.T198N | Missense Mutation (SNP) | VAF 50/654 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); called by muse, mutect2
- DUSP10 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 29/301 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- DYNC1I1 | c.1266G>T p.M422I | Missense Mutation (SNP) | VAF 21/328 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- EIF2AK4 | c.4259G>T p.W1420L | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ELP4 | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ELP4 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- FAM155B | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- FBN2 | c.6776A>T p.Q2259L | Missense Mutation (SNP) | VAF 101/480 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FGD5 | c.2764G>T p.V922F | Missense Mutation (SNP) | VAF 51/581 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- FOXC2 | c.1256C>A p.A419E | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2
- FOXRED2 | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 80/595 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FSTL4 | c.1678A>T p.S560C | Missense Mutation (SNP) | VAF 78/508 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- GPR148 | c.979C>A p.L327M | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2
- GPR149 | c.487C>A p.L163M | Missense Mutation (SNP) | VAF 55/318 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- GPR179 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPRC5C | c.686G>T p.G229V (on ENST00000652232; = p.G184V on NM_018653.4) | Missense Mutation (SNP) | VAF 60/473 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- GRID2IP | c.287C>A p.A96E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRK7 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 63/516 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- HEATR1 | c.3542G>T p.R1181I | Missense Mutation (SNP) | VAF 48/477 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- HECW1 | c.1336C>A p.Q446K | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); called by muse, mutect2
- IGHV3-66 | c.280A>T p.K94* | Nonsense Mutation (SNP) | VAF 41/738 reads (6%) | called by muse, mutect2
- INAVA | c.53G>T p.R18M | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); called by muse, mutect2
- INSR | c.1729G>T p.G577W | Missense Mutation (SNP) | VAF 50/359 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, varscan2
- ITIH5 | c.1929G>T p.M643I | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- ITLN1 | c.52A>T p.S18C | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- KALRN | c.91A>G p.I31V | Missense Mutation (SNP) | VAF 32/253 reads (13%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDM4A | c.489G>T p.E163D | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.033); called by muse, mutect2
- KIF17 | c.2321C>A p.A774E | Missense Mutation (SNP) | VAF 56/422 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- KRTAP5-3 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 59/424 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- KRTAP9-2 | c.157C>A p.R53S | Missense Mutation (SNP) | VAF 60/637 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.031); called by muse, mutect2
- LMOD3 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | called by muse, varscan2
- LRP1B | c.7093C>A p.P2365T | Missense Mutation (SNP) | VAF 89/648 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LUZP2 | c.230T>A p.L77Q | Missense Mutation (SNP) | VAF 20/315 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MADCAM1 | c.863C>A p.T288N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.029); called by muse, varscan2
- MAG | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- MARCHF1 | c.39C>A p.H13Q | Missense Mutation (SNP) | VAF 27/661 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2
- MCF2 | c.2152A>T p.R718* | Nonsense Mutation (SNP) | VAF 167/566 reads (30%) | called by muse, mutect2, varscan2
- MEIS2 | c.934T>G p.L312V (on ENST00000561208 / NM_170675.5; = p.L299V on NM_002399.3) | Missense Mutation (SNP) | VAF 55/558 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- MFAP3L | c.58A>T p.I20F | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.1); called by muse, mutect2
- MMP27 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 25/527 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.023); called by muse, mutect2
- MPO | c.123del p.T42Rfs*22 | Frame Shift Del (DEL) | VAF 68/561 reads (12%) | called by mutect2, pindel, varscan2
- MROH9 | c.2332G>T p.V778F | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.106); called by muse, mutect2
- MTTP | c.2251A>G p.I751V | Missense Mutation (SNP) | VAF 18/517 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MUC16 | c.16484C>A p.S5495Y | Missense Mutation (SNP) | VAF 87/540 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- MUC5B | c.16904C>A p.P5635Q | Missense Mutation (SNP) | VAF 58/452 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- NEGR1 | c.117C>A p.D39E | Missense Mutation (SNP) | VAF 28/476 reads (6%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.519); called by muse, mutect2
- NELFB | c.1051A>T p.M351L | Missense Mutation (SNP) | VAF 109/269 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- NFIL3 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.044); called by muse, mutect2
- NOX3 | c.1207G>T p.V403L | Missense Mutation (SNP) | VAF 34/438 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- NOX4 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 17/364 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.01); called by muse, mutect2
- NSMCE2 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- NUP205 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NXF3 | c.345G>T p.K115N | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NYAP1 | c.1993G>T p.G665C | Missense Mutation (SNP) | VAF 66/543 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- NYNRIN | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- OPN5 | c.1076G>C p.S359T | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); called by muse, mutect2
- OR2AK2 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- OR2T1 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52A5 | c.543C>A p.Y181* | Nonsense Mutation (SNP) | VAF 35/240 reads (15%) | called by muse, mutect2, varscan2
- PLRG1 | c.1499A>G p.H500R | Missense Mutation (SNP) | VAF 19/287 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2
- PLXNA4 | c.1156C>T p.L386F | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2
- PNLDC1 | c.1328A>T p.Q443L | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.071); called by muse, mutect2
- POPDC2 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 61/405 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- POTEF | c.2171A>C p.D724A | Missense Mutation (SNP) | VAF 26/791 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- POTEI | c.2334C>G p.N778K | Missense Mutation (SNP) | VAF 45/1036 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PRKCI | c.768G>T p.L256F | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PRSS48 | c.204C>A p.H68Q | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRT | c.81C>A p.S27R | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- PUS7 | c.1837G>T p.V613F | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PXDNL | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 48/532 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.475); called by muse, mutect2
- RAPSN | c.636G>T p.M212I | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.066); called by muse, mutect2
- RDH8 | c.980G>T p.R327L (on ENST00000651512; = p.R307L on NM_015725.4) | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- RESF1 | c.965A>T p.Q322L | Missense Mutation (SNP) | VAF 48/408 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- RXFP3 | c.922G>T p.V308L | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SCAND1 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- SEC16B | c.1518G>T p.M506I | Missense Mutation (SNP) | VAF 66/802 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2
- SHOC1 | c.1225+8C>A | Splice Region (SNP) | VAF 29/189 reads (15%) | called by muse, mutect2, varscan2
- SIRT3 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLC12A1 | c.2874-1G>A p.X958_splice | Splice Site (SNP) | VAF 51/333 reads (15%) | called by muse, mutect2, varscan2
- SLC25A21 | c.840T>A p.G280= | Splice Region (SNP) | VAF 62/400 reads (16%) | called by muse, mutect2, varscan2
- SLC26A3 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 37/763 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- SLC9A4 | c.2271G>C p.E757D | Missense Mutation (SNP) | VAF 64/575 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPATA31D1 | c.524C>A p.T175N | Missense Mutation (SNP) | VAF 40/686 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.282); called by muse, mutect2
- SPTBN5 | c.10748T>A p.V3583E | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- SYNE2 | c.17855T>C p.I5952T | Missense Mutation (SNP) | VAF 78/511 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SYT16 | c.815A>T p.Q272L | Missense Mutation (SNP) | VAF 67/543 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TBX15 | c.1034C>A p.T345K (on ENST00000369429 / NM_001330677.2; = p.T239K on NM_152380.3) | Missense Mutation (SNP) | VAF 83/753 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TBXAS1 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 144/1206 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TCHH | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 130/490 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- TGM6 | c.517C>G p.R173G | Missense Mutation (SNP) | VAF 36/313 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- TMEM178B | c.634G>C p.G212R | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM86A | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 61/455 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPM3 | c.4318C>A p.P1440T (on ENST00000357533 / NM_001366142.2; = p.P1295T on NM_020952.6) | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.29383A>T p.K9795* (on ENST00000591111; = p.K8868* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/600 reads (4%) | called by muse, mutect2
- UNC80 | c.2357A>G p.H786R | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- VCAN | c.8917C>T p.Q2973* | Nonsense Mutation (SNP) | VAF 71/358 reads (20%) | called by muse, mutect2, varscan2
- ZNF248 | c.564G>C p.K188N | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ZNF285 | c.649T>C p.S217P | Missense Mutation (SNP) | VAF 66/627 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF724 | c.682T>A p.C228S | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF727 | c.755G>C p.G252A | Missense Mutation (SNP) | VAF 62/458 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ZP2 | c.11G>T p.R4M | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); called by muse, mutect2
- ZPR1 | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 28/520 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.365); called by muse, mutect2
- ACOD1 | c.318G>T p.G106= | Silent (SNP) | VAF 54/413 reads (13%) | called by muse, mutect2, varscan2
- ACTN2 | c.570C>A p.I190= | Silent (SNP) | VAF 124/865 reads (14%) | catalogued as rs762515240; called by muse, mutect2, varscan2
- ACTN2 | c.1324C>A p.R442= | Silent (SNP) | VAF 39/748 reads (5%) | catalogued as COSV63978665; called by muse, mutect2
- ADAMTS7 | c.5022C>T p.G1674= | Silent (SNP) | VAF 44/304 reads (14%) | catalogued as rs527381278; called by muse, mutect2, varscan2
- ADCY9 | c.444C>T p.P148= | Silent (SNP) | VAF 55/628 reads (9%) | called by muse, mutect2
- ANGPT1 | c.774C>T p.V258= | Silent (SNP) | VAF 71/582 reads (12%) | called by muse, mutect2, varscan2
- ATP12A | c.1119G>T p.V373= | Silent (SNP) | VAF 40/363 reads (11%) | called by muse, varscan2
- CCDC188 | c.868C>A p.R290= | Silent (SNP) | VAF 35/252 reads (14%) | called by muse, mutect2, varscan2
- CCL23 | c.198T>A p.A66= | Silent (SNP) | VAF 52/632 reads (8%) | called by muse, mutect2
- CDH11 | c.843C>A p.A281= | Silent (SNP) | VAF 36/176 reads (20%) | catalogued as COSV51768799, COSV99217306; called by muse, mutect2, varscan2
- CRACD | c.2071T>C p.L691= | Silent (SNP) | VAF 25/358 reads (7%) | catalogued as rs754576633; called by muse, mutect2
- CSAG3 | c.336G>A p.R112= | Silent (SNP) | VAF 190/1244 reads (15%) | called by muse, mutect2, varscan2
- DNAH3 | c.4104C>A p.I1368= | Silent (SNP) | VAF 91/762 reads (12%) | called by muse, mutect2, varscan2
- DNAJC21 | c.153A>T p.A51= | Silent (SNP) | VAF 39/455 reads (9%) | called by muse, mutect2
- EBF1 | c.1500C>T p.G500= | Silent (SNP) | VAF 60/448 reads (13%) | catalogued as rs753073484, COSV58192663; called by muse, mutect2, varscan2
- EVC | c.1389G>T p.T463= | Silent (SNP) | VAF 87/802 reads (11%) | catalogued as COSV53829283, COSV53834148; called by muse, mutect2, varscan2
- FAM135B | c.3156T>G p.P1052= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- FAM47C | c.1248G>A p.S416= | Silent (SNP) | VAF 63/235 reads (27%) | catalogued as rs782664966, COSV100792852; called by muse, mutect2, varscan2
- FAR2 | c.537T>C p.D179= | Silent (SNP) | VAF 24/195 reads (12%) | called by muse, mutect2
- FOXD1 | c.1284C>A p.A428= | Silent (SNP) | VAF 84/276 reads (30%) | called by muse, mutect2, varscan2
- FRAS1 | c.3747A>T p.P1249= | Silent (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
- FSHR | c.1542G>A p.V514= | Silent (SNP) | VAF 19/293 reads (6%) | catalogued as rs1223686177; called by muse, mutect2
- GABRQ | c.474G>T p.V158= | Silent (SNP) | VAF 80/312 reads (26%) | catalogued as COSV64783882; called by muse, varscan2
- GJA3 | c.435G>A p.L145= | Silent (SNP) | VAF 71/441 reads (16%) | catalogued as rs1232490786; called by muse, mutect2, varscan2
- GJD4 | c.288C>G p.V96= | Silent (SNP) | VAF 36/468 reads (8%) | called by muse, mutect2
- GNA11 | c.60G>T p.R20= | Silent (SNP) | VAF 35/197 reads (18%) | called by muse, mutect2, varscan2
- GRID2 | c.1596T>C p.N532= | Silent (SNP) | VAF 36/226 reads (16%) | called by muse, mutect2, varscan2
- HEPHL1 | c.51T>A p.G17= | Silent (SNP) | VAF 33/264 reads (13%) | called by muse, mutect2, varscan2
- HRNR | c.2919T>C p.H973= | Silent (SNP) | VAF 282/1529 reads (18%) | catalogued as rs769556421, COSV64255603; called by muse, mutect2, varscan2
- KALRN | c.1593G>T p.R531= | Silent (SNP) | VAF 30/216 reads (14%) | catalogued as rs528746346, COSV99565324; called by muse, mutect2, varscan2
- KCNA6 | c.924C>T p.F308= | Silent (SNP) | VAF 26/499 reads (5%) | catalogued as rs868599709, COSV54976561; called by muse, mutect2
- KCNJ1 | c.144G>A p.R48= | Silent (SNP) | VAF 39/333 reads (12%) | catalogued as rs909572402, COSV100131199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT16 | c.819G>A p.E273= | Silent (SNP) | VAF 79/754 reads (10%) | called by muse, mutect2, varscan2
- KRTAP19-4 | c.100A>C p.R34= | Silent (SNP) | VAF 83/789 reads (11%) | catalogued as rs755580275; called by muse, mutect2, varscan2
- MUC3A | c.936C>A p.T312= | Silent (SNP) | VAF 77/488 reads (16%) | catalogued as rs77135444; called by muse, mutect2, varscan2
- MUC7 | c.186C>A p.S62= | Silent (SNP) | VAF 38/612 reads (6%) | catalogued as COSV59219841, COSV59220383; called by muse, mutect2
- MYH6 | c.4893C>A p.L1631= | Silent (SNP) | VAF 36/440 reads (8%) | called by muse, mutect2
- NLGN4X | c.1383G>T p.A461= | Silent (SNP) | VAF 85/366 reads (23%) | catalogued as rs763976516, COSV52015401, COSV52015454; called by muse, mutect2, varscan2
- OR4A16 | c.324A>C p.A108= | Silent (SNP) | VAF 38/424 reads (9%) | catalogued as COSV59042089; called by muse, mutect2
- OR4L1 | c.198C>A p.L66= | Silent (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- OR51I1 | c.693A>T p.I231= | Silent (SNP) | VAF 39/214 reads (18%) | catalogued as rs200066495; called by muse, mutect2, varscan2
- OTOF | c.3096T>A p.I1032= (on ENST00000272371 / NM_194248.3; = p.I285= on NM_004802.4) | Silent (SNP) | VAF 20/434 reads (5%) | called by muse, mutect2
- OTOGL | c.4926T>C p.S1642= (on ENST00000547103; = p.S1633= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 56/508 reads (11%) | called by muse, mutect2, varscan2
- OVCH1 | c.1770G>T p.V590= | Silent (SNP) | VAF 50/584 reads (9%) | called by muse, mutect2
- PAPPA | c.1050C>G p.P350= | Silent (SNP) | VAF 74/559 reads (13%) | called by muse, mutect2, varscan2
- PCDHB15 | c.1380C>T p.V460= | Silent (SNP) | VAF 150/788 reads (19%) | called by muse, mutect2, varscan2
- PDIK1L | c.990A>G p.V330= | Silent (SNP) | VAF 21/148 reads (14%) | called by muse, mutect2, varscan2
- PIK3CG | c.2229A>G p.Q743= | Silent (SNP) | VAF 79/571 reads (14%) | called by muse, mutect2, varscan2
- POTEI | c.351G>T p.V117= | Silent (SNP) | VAF 30/785 reads (4%) | called by muse, mutect2
- PPP1R3A | c.2280A>T p.A760= | Silent (SNP) | VAF 55/388 reads (14%) | called by muse, mutect2, varscan2
- R3HDM1 | c.2028A>G p.P676= | Silent (SNP) | VAF 29/404 reads (7%) | catalogued as COSV51532389; called by muse, mutect2
- RAPGEF6 | c.2010A>T p.S670= | Silent (SNP) | VAF 20/528 reads (4%) | catalogued as COSV99726030; called by muse, mutect2
- RXFP3 | c.921G>C p.A307= | Silent (SNP) | VAF 46/247 reads (19%) | catalogued as COSV57503839; called by muse, mutect2, varscan2
- SALL3 | c.3291C>A p.G1097= | Silent (SNP) | VAF 31/230 reads (13%) | catalogued as COSV101610052, COSV73306551; called by muse, mutect2, varscan2
- SEMA6A | c.2694C>A p.T898= | Silent (SNP) | VAF 87/490 reads (18%) | called by muse, mutect2, varscan2
- SFSWAP | c.2064G>T p.A688= | Silent (SNP) | VAF 84/541 reads (16%) | called by muse, mutect2, varscan2
- SLC22A7 | c.612T>G p.L204= (on ENST00000372585 / NM_153320.2; = p.L202= on NM_006672.3) | Silent (SNP) | VAF 77/680 reads (11%) | called by muse, mutect2, varscan2
- SLC45A3 | c.909C>A p.G303= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV65655827; called by muse, mutect2, varscan2
- STON2 | c.436C>T p.L146= | Silent (SNP) | VAF 56/520 reads (11%) | called by muse, mutect2, varscan2
- STON2 | c.435T>A p.P145= | Silent (SNP) | VAF 59/522 reads (11%) | called by muse, mutect2, varscan2
- SVEP1 | c.7440T>C p.C2480= | Silent (SNP) | VAF 27/171 reads (16%) | catalogued as rs928276779; called by muse, mutect2, varscan2
- TBL2 | c.294T>C p.F98= | Silent (SNP) | VAF 29/233 reads (12%) | called by muse, mutect2, varscan2
- TENM3 | c.7956G>A p.E2652= | Silent (SNP) | VAF 20/268 reads (7%) | catalogued as rs941834530; called by muse, mutect2
- TFAP2B | c.1236C>A p.A412= | Silent (SNP) | VAF 39/597 reads (7%) | catalogued as COSV53827488; called by muse, mutect2
- TUBA3C | c.318C>A p.G106= | Silent (SNP) | VAF 36/406 reads (9%) | called by muse, mutect2
- UBN1 | c.2034G>A p.K678= | Silent (SNP) | VAF 26/321 reads (8%) | catalogued as rs772503004; called by muse, mutect2
- UBN1 | c.2535G>A p.V845= | Silent (SNP) | VAF 35/592 reads (6%) | catalogued as rs1416468512; called by muse, mutect2
- UMOD | c.1222C>T p.L408= | Silent (SNP) | VAF 81/676 reads (12%) | called by muse, mutect2, varscan2
- VRTN | c.1683G>T p.P561= | Silent (SNP) | VAF 16/232 reads (7%) | catalogued as COSV56439887; called by muse, mutect2
- ZDBF2 | c.2133G>T p.P711= | Silent (SNP) | VAF 58/503 reads (12%) | called by muse, mutect2, varscan2
- ZDBF2 | c.3909G>A p.A1303= | Silent (SNP) | VAF 41/330 reads (12%) | catalogued as rs572059484; called by muse, mutect2, varscan2
- ZNF658 | c.606A>G p.K202= | Silent (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2
- ZSCAN20 | c.2754G>T p.L918= | Silent (SNP) | VAF 14/80 reads (18%) | called by muse, varscan2
- ABCC13 | n.3457C>A | RNA (SNP) | VAF 67/428 reads (16%) | catalogued as rs762966581; called by muse, mutect2, varscan2
- AC136759.1 | n.1449del | RNA (DEL) | VAF 132/1097 reads (12%) | called by mutect2, pindel, varscan2
- AEN | c.540+23G>T | Intron (SNP) | VAF 25/117 reads (21%) | called by muse, mutect2
- AHSG | c.-54G>T | 5'UTR (SNP) | VAF 85/454 reads (19%) | catalogued as rs763033096; called by muse, mutect2, varscan2
- BRCA1 | c.-20+105G>C | Intron (SNP) | VAF 33/260 reads (13%) | called by muse, mutect2, varscan2
- CFAP57 | c.1929+50G>T | Intron (SNP) | VAF 18/108 reads (17%) | catalogued as COSV65265392; called by muse, mutect2, varscan2
- COL6A4P1 | n.205C>A | RNA (SNP) | VAF 85/761 reads (11%) | called by muse, mutect2, varscan2
- DCHS2 | n.2411C>A | RNA (SNP) | VAF 37/244 reads (15%) | called by muse, mutect2, varscan2
- DCX | c.-22-341C>G | Intron (SNP) | VAF 83/507 reads (16%) | called by muse, mutect2, varscan2
- DRD2 | c.723+34C>T | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- DSTYK | c.-1G>A | 5'UTR (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- ELP4 | c.1146+31839G>A | Intron (SNP) | VAF 24/196 reads (12%) | called by muse, varscan2
- EPHA8 | c.*18C>T | 3'UTR (SNP) | VAF 46/703 reads (7%) | called by muse, mutect2
- FAM135B | c.77+552T>C | Intron (SNP) | VAF 31/283 reads (11%) | catalogued as rs937696714; called by muse, mutect2, varscan2
- FAM86DP | n.734G>A | RNA (SNP) | VAF 76/602 reads (13%) | catalogued as rs753052177; called by muse, mutect2, varscan2
- GPATCH2L | c.-11+666_-11+674del | Intron (DEL) | VAF 50/438 reads (11%) | called by mutect2, pindel
- GPR137B | c.-24G>T | 5'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- HGF | c.-11C>A | 5'UTR (SNP) | VAF 120/887 reads (14%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.492C>A | RNA (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- IQCF3 | c.19-23C>T | Intron (SNP) | VAF 35/208 reads (17%) | called by muse, mutect2, varscan2
- KAT8 | chr16:31117647 T>A | 5'Flank (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- KRT17P1 | n.948C>T | RNA (SNP) | VAF 16/152 reads (11%) | called by mutect2, varscan2
- MEIS3 | c.859-96C>A | Intron (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- MIR376B | n.6C>G | RNA (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- NDUFAF4P1 | chr15:49161743 G>T | 3'Flank (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- NFATC1 | c.127+4125C>A | Intron (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- NPIPA8 | chr16:18340264 A>T | 5'Flank (SNP) | VAF 71/578 reads (12%) | called by muse, mutect2, varscan2
- OVCH1 | c.893-552T>C | Intron (SNP) | VAF 40/250 reads (16%) | called by muse, mutect2, varscan2
- PNCK | c.-2-245G>C | Intron (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- PRKCG | c.*38C>A | 3'UTR (SNP) | VAF 16/117 reads (14%) | catalogued as rs1178230107; called by muse, mutect2, varscan2
- RAB11FIP2 | c.1265+4981G>T | Intron (SNP) | VAF 66/609 reads (11%) | called by muse, mutect2, varscan2
- RARA | c.179-5479C>T | Intron (SNP) | VAF 31/237 reads (13%) | catalogued as COSV54197004; called by muse, mutect2, varscan2
- SIK3 | c.1788+122G>T | Intron (SNP) | VAF 20/418 reads (5%) | called by muse, mutect2
- STAT3 | c.1366-51G>T | Intron (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- TBX15 | c.*24C>A | 3'UTR (SNP) | VAF 48/390 reads (12%) | called by muse, mutect2, varscan2
- TCEANC2 | c.*8199A>G | 3'UTR (SNP) | VAF 6/90 reads (7%) | catalogued as rs1356049508; called by muse, mutect2
- TTYH3 | c.124-1057G>T | Intron (SNP) | VAF 33/259 reads (13%) | called by muse, mutect2, varscan2
- USP4 | c.696-5621G>T | Intron (SNP) | VAF 55/483 reads (11%) | called by muse, mutect2, varscan2
- VCX3A | c.*72C>T | 3'UTR (SNP) | VAF 63/348 reads (18%) | catalogued as COSV101130012; called by muse, varscan2
- ZRSR2 | c.203+1536A>C | Intron (SNP) | VAF 4/32 reads (13%) | catalogued as rs1199400991; called by muse, mutect2
